Surgical pathology report (de-identified scan), TCGA case TCGA-ZK-AAYZ, project TCGA-CHOL (Cholangiocarcinoma), tissue source site University of New Mexico, specimen TCGA-ZK-AAYZ-01A (Primary Tumor).

[page 1 of 4]
Result type: Surgical Pathology Final Report

Result date:

Result status: Auth (Verified)

Result title: Surgical Procedure

Performed by:

Verified by:

Encounter info:

Contributor system:

* Final Report *

Surgical Procedure

CASE:

PATIENT:

SPECIMENS SUBMITTED:

- A. PERITONEAL IMPLANT
- B. ADDITIONAL PERITONEAL BIOPSY
- C. GASTRO HEPATIC LYMPH NODE
- D. PERIPANCREATIC LYMPH NODE
- E. GALLBLADDER
- F. RIGHT LOBE OF LIVER WITH INTRAHEPATIC MASS
- G. CYSTIC DUCT NODE

DIAGNOSIS:

- A. ABDOMEN, SUBMITTED AS PERITONEAL IMPLANT; BIOPSY:
- MESOTHELIUM AND FIBROUS TISSUE, NEGATIVE FOR MALIGNANCY
- B. ABDOMEN, PERITONEUM; BIOPSY:
- MESOTHELIUM, SKELETAL MUSCLE AND FIBROUS TISSUE, NEGATIVE FOR MALIGNANCY
- C. LYMPH NODE, GASTROHEPATIC; EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1)
- D. LYMPH NODE, PERIPANCREATIC; EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1)
- E. GALLBLADDER; CHOLECYSTECTOMY:
- CHRONIC CHOLECYSTITIS

ICD.O-3
Cholangiocarcinoma 8160/3
Site Intrahepatic bile duct C22.1
J 3/10/14

[page 2 of 4]
- NEGATIVE FOR ATYPIA AND MALIGNANCY
- F. LIVER, RIGHT LOBE; RESECTION:
- INVASIVE ADENOCARCINOMA, MODERATELY-TO-POORLY DIFFERENTIATED, CONSISTENT WITH INTRAHEPATIC CHOLANGIOCARCINOMA IN THE CORRECT CLINICAL CONTEXT (SEE COMMENT)
- TUMOR SIZE: 4.2 CM
- LYMPH-VASCULAR SPACE INVASION: NEGATIVE
- PERINEURAL INVASION: PRESENT, EXTENSIVE
- MARGIN: LIVER PARENCHYMAL MARGIN IS NEGATIVE BUT CLOSE (1 MM)
- TUMOR AJCC STAGE: pT1 N0
- G. LYMPH NODE, CYSTIC DUCT NODE; EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1)

COMMENT: The findings are of an invasive adenocarcinoma. Tumor cells are positive for cytokeratin 7 and are negative for cdx2, estrogen receptor, and TTF-1 and napsin. Although tumor cells are positive for cytokeratin 20, the normal biliary epithelium also stains for cytokeratin 20 in the same slide as tumor. In the context of an isolated liver-based mass, the findings are most in keeping with a cholangiocarcinoma. Selected H+E slides were reviewed with concurrence by [REDACTED].

INTRAOPERATIVE DIAGNOSIS:

FSA: Peritoneal implant (FSA): Benign mesothelium with fibrous tissue. Negative for malignancy.

FSB: Additional peritoneal biopsy (FSB): Mesothelium fibrous tissue and skeletal muscle. Negative for malignancy.

FSC: Gastro hepatic Lymph node (FSC): One lymph node negative for malignancy.

FSF: Right lobe of liver with intrahepatic mass (FSF): Adenocarcinoma close to parenchymal margin (1 mm). [REDACTED].

CLINICAL INFORMATION: [REDACTED].

GROSS DESCRIPTION: Number of specimen containers: 7. Labeled with patient name [REDACTED] and MRN [REDACTED].

A. Container designation: "peritoneal implant" -- Received unfixed is a

[page 3 of 4]
0.3 cm aggregate of pink-tan soft tissue which is submitted entirely for frozen section, wrapped and submitted for permanent in A1.

B. Container designation: "additional peritoneal biopsy" -- Received unfixed are multiple fragments of pink-tan to yellow soft tissue aggregating to 0.8 x 0.4 x 0.2 cm. The specimen is submitted entirely for frozen section, leveled and the frozen section remnants are wrapped and submitted for permanent in B1.

C. Container designation: "gastro hepatic lymph node" -- Received unfixed is a yellow-tan lymph node 0.6 x 0.6 x 0.5 cm. The specimen is bisected. Touch preps are performed. The specimen is submitted entirely for frozen section, leveled and the frozen section remnant is wrapped and submitted for permanent in C1.

D. Container designation: "peripancreatic node" -- Received is a mahogany tan lymph node 0.8 x 0.5 x 0.5 cm. The specimen is bisected, wrapped and submitted entirely in D1.

E. Container designation: "gallbladder" - Gallbladder size: 7.5 x 4.0 cm. Wall thickness: up to 0.6 cm. Stones: number: none. Mucosa: yellow tinged, velvety, focally congested. Serosa: purple-red and scattered petechiae. Masses: none. Cystic duct patent: yes. Cystic duct lymph node: none. Cassettes: representative sections of the fundus, body, neck and cystic duct (inked) in E1.

F. Container designation: "right lobe of liver with intrahepatic mass" - - Received fresh for frozen section is a 457.3 gram (16 x 13 x 7 cm) lobe of liver. The parenchymal margin is inked in green and the specimen is serially sectioned to reveal a green tinged and red parenchyma with dilated vessels throughout as well as a 4.2 x 3.8 x 3.5 cm well defined white-yellow glistening lesion that is located within 1 mm of the resection margin. Representative section is submitted for frozen section and the remnants in cassettes F1 and F2. The specimen is photographed for documentation. The external surface is purple red and free of grossly identifiable nodules or adhesions. No additional nodules are grossly appreciated. Representative in 10 cassettes as follows: F1 - F2 - frozen section remnants; F3 - F4 - lesion nearest margin adjacent to frozen section; F6 - F7 - lesion with surrounding fibrous tissue and parenchyma; F8 - F10 - representative of uninvolved parenchyma.

G. Container designation: "cystic duct node" -- Received unfixed is a

[page 4 of 4]
0.8 x 0.5 x 0.2 cm possible lymph node which is bisected with tan homogeneous cut surfaces and entirely submitted in cassette G1.

(Dictated by: [REDACTED], specimens A - E) (Dictated by: [REDACTED]
[REDACTED], specimen F) ([REDACTED])

MICROSCOPIC DESCRIPTION: Histologic examination performed.

Any tests performed using Analytic Specific Reagents (ASR) were developed and validated by [REDACTED]. The U.S. Food and Drug Administration has not approved these tests but has determined that such clearance or approval is not necessary. These tests should be regarded as a clinical assay for standard medical care.

The [REDACTED] was present during the formal review and interpretation of all slides and ancillary studies, (if performed), with the [REDACTED]. Specimens with only gross examination were reviewed and interpreted by the [REDACTED].

Final Diagnosis performed by

[REDACTED]

Testing performed at:

[REDACTED]

Source: NCI Genomic Data Commons file d656efc3-a012-4d5a-b85f-89d60ecc17a8 (TCGA-ZK-AAYZ.225464AC-D403-439B-A128-D0E656603EA6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).